TCGA case TCGA-22-1017 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25f64b80-0672-4980-9875-956b1699309b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Dead; Days to death: 1,485 days (4.1 years).

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,880 days); Year of diagnosis: 1999; AJCC staging edition: 5th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Residual disease: R0; Days to last follow up: 1,485 days (4.1 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenosquamous carcinoma: ICD-O-3 morphology code: 8560/3; Tissue or organ of origin: Lung, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 62.2 years (22,718 days); Days to diagnosis: -162 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -162 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 65.1 years (23,784 days); Days to diagnosis: 904 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,022 days (2.8 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (5 entries)
- Day 904 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 904 days (2.5 years); Evidence of recurrence type: Convincing Image Source.
- Day 904 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 904 days (2.5 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,485 days (4.1 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.
- Karnofsky performance status: 0.

Other clinical attributes
- DLCO (% of predicted): 60; FEV1/FVC after bronchodilator (%): 68; FEV1/FVC before bronchodilator (%): 61; FEV1 after bronchodilator (% of reference): 75; FEV1 before bronchodilator (% of reference): 58.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 1999.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-22-1017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-22-1017-01A-01-BS1: Section location: Bottom; Percent tumor nuclei: 80; Percent necrosis: 5.
  Slide TCGA-22-1017-01A-01-TS1: Section location: Top; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample TCGA-22-1017-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-22-1017-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence; New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Adenosquamous.
- Other malignancy form, Surgery: Other malignancy surgery type: Wedge Resection.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject Positive for Neo-Adjuvant Therapy.
- Neoadjuvant therapy: Prior malignancy and neo-adjuvant treatment per enrollment form.
- Prior malignancy: Prior malignancy and neo-adjuvant treatment per enrollment form.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,485 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,485 days; disease-free interval: event (new tumor event after initially disease-free), 904 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 904 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-22-1017-01): tumor purity 0.34, ploidy 3.33, whole-genome doublings 1 (call status: snp_call).
